Gene-level copy-number profile of tumor specimen TCGA-61-1899-01A from TCGA case TCGA-61-1899, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.3 years (29,692 days).
Specimen TCGA-61-1899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0056b0fa-8cd7-4e78-a76b-9c616246f9c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1899-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3780589c-e432-4649-8bb5-8faa626d82c3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4,775; copy number 2: 12,290; copy number 3: 18,769; copy number 4: 17,957; copy number 5: 4,023; copy number 6: 588; copy number 7: 260; copy number 8: 703; copy number 9: 9; copy number 10: 62; copy number 11: 46; copy number 12: 139; copy number 13: 13; copy number 14: 56; copy number 19: 5; copy number 29: 2; copy number 31: 46; copy number 33: 62; copy number 36: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1899-01A-01D-0577-01): tumor purity 0.78, ploidy 6.21, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,412 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,881,566–40,097,260, 8 genes, copy number 7: Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1.
- chr1:143,343,180–155,227,422, 542 genes, copy number 7–8 (broad region; genes not listed).
- chr1:201,982,372–202,096,978, 9 genes, copy number 9 (within-gene range 3–9): RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3.
- chr2:44,065,894–44,361,862, 9 genes, copy number 7: AC019129.1, RNU6-566P, PDSS1P2, AC019129.2, PPM1B, AC013717.1, RPL12P19, SLC3A1, PREPL.
- chr5:170,763,350–170,814,047, 1 gene, copy number 7 (within-gene range 1–7): GABRP.
- chr5:170,866,835–170,904,461, 2 genes, copy number 7: RN7SL623P, AC008514.2.
- chr12:2,676,001–4,305,353, 47 genes, copy number 8: CACNA1C-AS1, ITFG2-AS1, AC092471.2, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2.
- chr12:4,323,724–4,324,811, 1 gene, copy number 8: AC006122.1.
- chr12:5,531,869–5,946,232, 1 gene, copy number 8 (within-gene range 2–8): ANO2.
- chr12:5,948,877–7,071,032, 75 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr12:7,237,432–12,211,084, 220 genes, copy number 7–10 (within-gene range 2–10) (broad region; genes not listed).
- chr12:12,155,262–12,155,772, 1 gene, copy number 7: AC007537.1.
- chr12:22,063,773–22,437,041, 1 gene, copy number 8 (within-gene range 2–8): ST8SIA1.
- chr12:22,195,469–27,066,343, 76 genes, copy number 8–14 (within-gene range 6–14) (broad region; genes not listed).
- chr12:29,277,397–32,646,050, 83 genes, copy number 8 (broad region; genes not listed).
- chr19:18,683,678–21,852,125, 150 genes, copy number 12–31 (broad region; genes not listed).
- chr19:27,638,483–31,787,255, 81 genes, copy number 11–31 (broad region; genes not listed).
- chr19:36,014,508–37,403,846, 62 genes, copy number 33 (broad region; genes not listed).
- chr21:16,505,555–19,345,312, 43 genes, copy number 10–36: AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P.

Autosomal genes at a single copy (total copy number 1): 3,531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
